Somatic mutation profile of tumor specimen TARGET-20-PARVAF-09A (aliquot TARGET-20-PARVAF-09A-01D) from TARGET case TARGET-20-PARVAF, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,233 days).
Specimen TARGET-20-PARVAF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7f76c96-dbd0-4cd2-bcd8-44add66f0db5.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARVAF-14A (Bone Marrow Normal), aliquot TARGET-20-PARVAF-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f7b6613-9c1a-4876-b269-f25c54c81eb8

The open-access MAF lists 1 somatic variant for this specimen: 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TPTE | chr21:10605850 A>C | 3'Flank (SNP) | VAF 14/174 reads (8%) | called by muse, mutect2
